CPTAC case 26OV002 — Ovary — Cystic, Mucinous and Serous Neoplasms (CPTAC-2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/a7deae0d-38d2-46e4-a90b-f79f57fd2808

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino.

Diagnoses (1)
1. Serous adenocarcinoma, NOS: ICD-O-3 morphology code: 8441/3; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Prior malignancy: no.

Biospecimens (2 samples)
- Sample 6319b36b-533c-4e86-8e12-80552e: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 70daa657-8dd1-48e7-a69b-e3d7d1: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
